Surgical pathology report (de-identified scan), TCGA case TCGA-X7-A8DC, project TCGA-THYM (Thymoma), tissue source site ABS IUPUI, specimen TCGA-X7-A8DC-01A (Primary Tumor).

[page 1 of 3]
Operative Procedure:
Thymoma resection VATS.

Specimen Received:
Anterior mediastinal mass (FS)

Final Pathologic Diagnosis:
Anterior mediastinal mass, resection:
Thymoma, WHO type AB.
Tumor measures 6.8x 5.6x 3.6cm.
Soft tissue and mesothelial margins free of tumor.
Tumor capsule is within 1mm of inked margin.
No evidence of angiolymphatic or perineural invasion.

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Note:
The tumor cells are positive for cytokeratin (AE1/3 and cocktail) and CD5 expression is restricted to lymphoid cells.

Intraoperative Consult Diagnosis:
FS: Anterior mediastinal mass:
Lymphocyte rich neoplasm.
Defer to permanent sections for a definitive diagnosis.
Tissue submitted for ancillary (flow cytometry studies).
FS TAT: 17 mins.

Gross Description:

The specimen is received fresh for intraoperative consultation with the patient name, labeled "anterior mediastinal mass" and consists of a previously inked and incised, irregular, lobulated, rubbery mass that has dimensions of 6.8 x 5.6 x 3.6 cm. The specimen is partially surfaced by an apparent mesothelial lining that has dimensions of 7.0 x 4.5 cm. This lining is pink-tan to red-brown and predominately smooth and glistening with mild focal hemorrhage. The remainder of the external surface is somewhat shaggy. The specimen is further inked and sectioned to reveal a pink-tan, lobulated cut surface that is remarkable for mild focal hemorrhage. There is no degeneration identified. The mesothelial lining is freely mobile over this mass. Also, this mass extends to within 1 mm of the inked external surface. Also, there is some associated gray-yellow, lobulated and glistening tissue that may represent thymic tissue. There are no discrete lymph nodes identified. Some of the tissue has been retained in _____, touch preps performed and submitted to hematology. A representative section has been submitted for frozen section diagnosis and the residue resubmitted for permanent sections in cassette 1 while additional representative sections are submitted in cassettes 2 through 10 to

ICD-O-3
Thymoma, type AB NOS 8582/3
Site: ^{CHE} Thymus C37.9
^{path} Mediastinum, anterior C38.1
JG 6/13/14

[page 2 of 3]
include mesothelial lining in cassettes 2 and 3, inked external surface in cassettes 4 through 9 and possible thymus in cassette 10.

Flow Cytometry

Interpretation

Flow cytometric analysis shows a population of immature and mature T cells. The immature T cell population expresses CD5 (heterogenous, dim), cytoplasmic CD3, CD7, CD2, CD1a, TdT, CD10 and CD34 (subpopulation). These cells express either CD4 and CD8 (24%), heterogenous CD4, or CD8. Correlation with morphology recommended for further classification.

Results-Comments

Gated cells represent 91% of total sample

ANTIBODY % POSITIVE CELLS IN BLAST GATE

B-RELATED

CD19	1	
CD20	<1	
CD20+/CD5+		<1
CD10	77	

CD19 positive population

CD19/Kappa	<1	
CD19/Lambda	<1	

T-RELATED

CD7	95	
CD2	99	
CD5	98	
CD3	19	
CD4	79	
CD8	34	

MYELOID/OTHER

CD34	9	
CD34+/CD56+		<1
CD33	11	
CD13	1	
CD13+/CD7+		<1
CD15	<1	
CD117	<1	
CD15+/CD117+		<1
CD64	1	
CD14	1	
CD11b	6	
CD61	<1	

[page 3 of 3]
CD56	3	
HLA-DR	4	
CD71	31	
CD38	95	
TdT	89	
Cytoplasmic CD3		100
CD1a	94	

Viability: 87%

Morphologic review of cytospin demonstrates lymphoid cells.

END OF REPORT

Taken:

DOB:

Gender: M

Source: NCI Genomic Data Commons file b498dd14-83f2-4ce0-bf47-69b955912857 (TCGA-X7-A8DC.6661D3B5-BD94-4286-BF54-17FA019F8E10.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).